Gene-level copy-number profile of tumor specimen TCGA-55-8506-01A from TCGA case TCGA-55-8506, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.6 years (22,850 days).
Specimen TCGA-55-8506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.27893abf-a34a-411b-95e7-5591722546e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8506-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f00b5e9c-13b9-4190-9ad9-12d86374f571

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 28; copy number 2: 8,494; copy number 3: 8,085; copy number 4: 26,980; copy number 5: 6,837; copy number 6: 6,396; copy number 7: 1,354; copy number 8: 476; copy number 9: 167; copy number 10: 125; copy number 11: 520; copy number 13: 7; copy number 15: 342.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8506-01A-11D-2389-01): tumor purity 0.45, ploidy 3.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,161 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,535,078–160,780,140, 59 genes, copy number 9: OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2, CRPP1, CRP, AL445528.1, DUSP23, FCRL6, SLAMF8, AL590560.2, SNHG28, AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2.
- chr1:163,769,339–165,827,755, 32 genes, copy number 9 (within-gene range 7–9): AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1.
- chr1:166,975,582–167,195,792, 7 genes, copy number 10 (within-gene range 7–10): MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363.
- chr1:175,877,343–178,484,147, 29 genes, copy number 9 (within-gene range 7–9): LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7, AL031290.1, ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1.
- chr1:232,160,091–235,161,283, 65 genes, copy number 9–11 (broad region; genes not listed).
- chr1:235,190,034–235,190,116, 1 gene, copy number 11: MIR4753.
- chr5:58,198–45,895,970, 710 genes, copy number 11–15 (broad region; genes not listed).
- chr7:7,356,203–7,535,873, 1 gene, copy number 9 (within-gene range 5–9): COL28A1.
- chr9:97,674,909–97,856,717, 5 genes, copy number 9 (within-gene range 5–9): XPA, KRT18P13, PTCSC2, AL445531.1, FOXE1.
- chr11:98,676,391–102,903,953, 51 genes, copy number 11: AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P.
- chr14:34,981,957–37,579,125, 62 genes, copy number 11 (broad region; genes not listed).
- chr14:49,618,530–52,069,228, 86 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr14:67,819,779–68,730,218, 1 gene, copy number 9 (within-gene range 6–9): RAD51B.
- chr14:68,125,004–69,023,308, 20 genes, copy number 9–13: AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1.
- chr16:11,547,722–11,828,845, 8 genes, copy number 10 (within-gene range 6–10): LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr22:36,137,430–36,552,700, 23 genes, copy number 10: Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1, MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1, AL022313.3.
- chr22:36,560,870–36,562,915, 1 gene, copy number 10: AL022313.4.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
